Somatic mutation profile of tumor specimen MP2PRT-PAUJKU-TMP1-A (aliquot MP2PRT-PAUJKU-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUJKU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,182 days).
Specimen MP2PRT-PAUJKU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58e42f63-b7a7-4933-8002-19d52b7a0f64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJKU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJKU-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/326e6015-7555-4c4c-b006-bf5467366221

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCAF8L1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 89/102 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71595349; called by muse, mutect2, varscan2
- DGKK | c.2015C>G p.T672S | Missense Mutation (SNP) | VAF 156/181 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV65706599; called by muse, mutect2, varscan2
- MEGF10 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57245215, COSV57247597; called by muse, mutect2, varscan2
- OR6Y1 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 199/455 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.821); catalogued as COSV56930555; called by muse, mutect2
- SGSM1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 212/452 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1345151399, COSV68509010; called by muse, mutect2, varscan2
- BMP7 | c.636C>A p.D212E | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BRCA2 | c.3059C>G p.S1020C | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTBD2 | c.1566C>G p.I522M | Missense Mutation (SNP) | VAF 136/293 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK4 | c.458C>A p.T153K | Missense Mutation (SNP) | VAF 237/538 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK2 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); called by muse, mutect2
- LAMC3 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 216/546 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- NBEA | c.8639G>A p.G2880E | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCR3LG1 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 177/367 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRKAA1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by mutect2, varscan2
- RARS2 | c.729A>T p.K243N | Missense Mutation (SNP) | VAF 165/380 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZNF729 | c.2271A>C p.K757N | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- GPC1 | c.1086C>A p.G362= | Silent (SNP) | VAF 258/569 reads (45%) | called by muse, mutect2
- IQCA1 | c.1527C>T p.I509= | Silent (SNP) | VAF 99/300 reads (33%) | called by muse, mutect2, varscan2
- GABRD | c.554-65C>T | Intron (SNP) | VAF 186/442 reads (42%) | catalogued as rs567046589; called by muse, varscan2
